CCG case CUPP-B7PM — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1fcdd30d-ebec-4982-8932-ab01d898550a

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 458 days (1.3 years); Year of death: 2008; Cause of death: Not Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 2007; Prior malignancy: no.

Follow-up (1 entry)
- Days to follow up: 458 days (1.3 years); Year of follow up: 2008.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7PM-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7PM-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 35; Percent normal cells: 25; Percent necrosis: 5; Percent stromal cells: 40; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
